Somatic mutation profile of tumor specimen TCGA-2G-AALW-01A (aliquot TCGA-2G-AALW-01A-11D-A42Y-10) from TCGA case TCGA-2G-AALW, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AALW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 890c66b1-1b00-4872-b43a-07a5541a0d35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AALW-10A (Blood Derived Normal), aliquot TCGA-2G-AALW-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ead95d3-2823-40d1-b547-715ff86564f8

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Frame Shift Del 4, Silent 4, Translation Start Site 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIVM-ERCC5 | c.4027C>G p.L1343V | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63244654; called by muse, mutect2, varscan2
- CARD17 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.733); catalogued as COSV65214634, COSV65214682; called by muse, mutect2, varscan2
- IFIT5 | c.1169G>C p.R390P | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV65655961; called by muse, mutect2, varscan2
- PHF20L1 | c.2122G>A p.V708M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs1040450099, COSV55191877; called by muse, mutect2, varscan2
- RIMBP2 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs774346465, COSV55480309; called by muse, mutect2, varscan2
- AFDN | c.5044_5057del p.G1682Sfs*49 (on ENST00000447894 / NM_001366320.1; = p.X1665_splice on NM_001207008.1) | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- C7orf26 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- CLOCK | c.1127T>C p.V376A | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- EPAS1 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCHSD1 | c.992G>T p.R331L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- FCHSD1 | c.991C>A p.R331S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GLRB | c.328A>G p.K110E | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IL4R | c.1877G>T p.S626I | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2
- KMT2D | c.2649C>A p.F883L | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC41 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- NCAM2 | c.512T>A p.L171Q | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PF4V1 | c.40C>G p.R14G | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- POTEE | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 92/341 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- SLAMF8 | c.226T>G p.F76V | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SMARCA5 | c.3023_3026del p.I1008Kfs*7 | Frame Shift Del (DEL) | VAF 25/78 reads (32%) | called by pindel, varscan2
- TBC1D10A | c.518del p.G173Afs*11 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- TLR7 | c.97del p.T33Lfs*15 | Frame Shift Del (DEL) | VAF 59/356 reads (17%) | called by mutect2, pindel, varscan2
- TRPC3 | c.1595A>G p.E532G (on ENST00000379645 / NM_001366479.2; = p.E459G on NM_003305.2) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- CYLC1 | c.1101A>G p.P367= | Silent (SNP) | VAF 61/132 reads (46%) | called by muse, mutect2, varscan2
- E4F1 | c.1692G>A p.R564= | Silent (SNP) | VAF 37/157 reads (24%) | catalogued as rs933196864; called by muse, mutect2, varscan2
- KLK5 | c.237G>T p.P79= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV100306753; called by muse, mutect2, varscan2
- MTRF1L | c.153G>A p.A51= | Silent (SNP) | VAF 45/181 reads (25%) | called by muse, mutect2, varscan2
- MS4A2 | c.537+39G>T | Intron (SNP) | VAF 54/137 reads (39%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2578C>A | RNA (SNP) | VAF 39/104 reads (38%) | called by muse, mutect2, varscan2
